Somatic mutation profile of tumor specimen TCGA-26-1799-01A (aliquot TCGA-26-1799-01A-02W-0643-08) from TCGA case TCGA-26-1799, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.9 years (25,171 days).
Specimen TCGA-26-1799-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 035e9f51-1e08-4d5c-b175-ce33bb588e70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-1799-10A (Blood Derived Normal), aliquot TCGA-26-1799-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb84d4d0-423a-4d66-a5c8-41b287f623f8

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Frame Shift Del 7, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.12457A>G p.K4153E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV99948598; called by muse, mutect2, varscan2
- C2CD6 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376409092; called by muse, mutect2, varscan2
- CDC73 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100813933; called by muse, mutect2
- COP1 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1362163964, COSV100443649, COSV58176541; called by muse, mutect2, varscan2
- CYP3A43 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99733470; called by muse, mutect2, varscan2
- DNAH3 | c.7262G>A p.R2421H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200916697, COSV54547235; called by muse, mutect2, varscan2
- F13A1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 162/823 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs140712764; called by muse, mutect2, varscan2
- FAM47A | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100649994; called by muse, mutect2, varscan2
- FAT4 | c.4461A>T p.E1487D | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101272533; called by muse, mutect2, varscan2
- FFAR2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs552300357, COSV55831776; called by muse, mutect2, varscan2
- FMO1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100707859; called by muse, mutect2, varscan2
- FSTL4 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 136/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99533269; called by muse, mutect2, varscan2
- GLYR1 | c.1132del p.R378Gfs*23 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs780981191, COSV58927238, COSV58927479; called by mutect2, pindel
- ITM2B | c.454-1G>A p.X152_splice | Splice Site (SNP) | VAF 55/106 reads (52%) | catalogued as COSV101052353; called by muse, varscan2
- MANEAL | c.1102C>T p.R368W (on ENST00000373045 / NM_001113482.1; = p.R146W on NM_152496.2) | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766770261, COSV100203947; called by muse, mutect2, varscan2
- NEIL3 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs765871055, COSV52809365, COSV99220775; called by muse, mutect2, varscan2
- NPY5R | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100642861; called by muse, mutect2, varscan2
- PAGE5 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99215806; called by muse, mutect2, varscan2
- PATJ | c.1514T>A p.L505* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as rs932390738; called by muse, mutect2, varscan2
- PCDHGA5 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as COSV53896726; called by muse, mutect2, varscan2
- PLEKHG4B | c.2614C>T p.R872C (on ENST00000283426; = p.R1228C on NM_052909.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs542193129, COSV99360758; called by muse, varscan2
- PMVK | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214782873, COSV100870522; called by muse, mutect2, varscan2
- SEC24A | c.2593G>C p.D865H | Missense Mutation (SNP) | VAF 150/323 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1324447212, COSV101295038; called by muse, mutect2, varscan2
- SEC61A1 | c.978C>A p.D326E | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99684948; called by muse, mutect2
- SI | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100016443; called by muse, mutect2
- STRADB | c.194-1G>T p.X65_splice | Splice Site (SNP) | VAF 12/288 reads (4%) | catalogued as COSV99524683; called by muse, mutect2
- SV2C | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.28); catalogued as rs779123910, COSV100456147; called by muse, mutect2, varscan2
- TET1 | c.1069del p.E357Kfs*9 | Frame Shift Del (DEL) | VAF 47/78 reads (60%) | catalogued as COSV101018163; called by mutect2, pindel, varscan2
- TLR2 | c.1723G>T p.V575F | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99472438; called by muse, mutect2, varscan2
- TNIP1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs145527698; called by muse, mutect2, varscan2
- TRAT1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99849393; called by muse, mutect2, varscan2
- VPS13A | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62425835; called by muse, mutect2
- ACVR2B | c.802del p.H268Mfs*23 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- AGL | c.3480del p.C1160* | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | called by mutect2, pindel, varscan2
- ANK1 | c.3127del p.L1043Wfs*4 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- FLG2 | c.5278_5281del p.E1760Pfs*2 | Frame Shift Del (DEL) | VAF 88/531 reads (17%) | called by pindel, varscan2
- MRTFA | c.1373del p.E458Gfs*2 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ANPEP | c.120C>T p.N40= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs568774558, COSV100263330, COSV100263454; called by muse, varscan2
- ANXA2R | c.48A>T p.A16= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100148700; called by muse, mutect2, varscan2
- CES3 | c.648C>T p.F216= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs768694829, COSV57592693; called by muse, varscan2
- CPLX2 | c.9C>T p.F3= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs775793619, COSV100853097; called by muse, mutect2, varscan2
- MINDY4 | c.1128G>T p.R376= | Silent (SNP) | VAF 37/893 reads (4%) | catalogued as COSV99519032; called by muse, mutect2
- MUTYH | c.1311G>A p.G437= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100588093; called by muse, varscan2
- PCDHA5 | c.1143C>T p.N381= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100972457; called by muse, mutect2, varscan2
- SLC24A3 | c.876C>T p.D292= | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as rs375163147; called by muse, mutect2
- SLCO6A1 | c.12C>T p.G4= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV65808930; called by muse, mutect2, varscan2
- ST8SIA3 | c.717C>T p.D239= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs150038577; called by muse, mutect2, varscan2
- SULT1E1 | c.732C>T p.D244= | Silent (SNP) | VAF 83/477 reads (17%) | catalogued as rs546191623, COSV99895119; called by muse, mutect2, varscan2
- TNFRSF1B | c.1146C>T p.T382= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs549171418, COSV100884182; called by muse, mutect2, varscan2
- ZMAT4 | c.67C>T p.L23= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99910702; called by muse, mutect2, varscan2
